TARGET case TARGET-15-SJMPAL012425 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/56cd353a-4402-43a6-a5b5-95b90dbfef50

Demographics
Sex at birth: female; Age at index: 13 years; Vital status: Dead; Days to death: 591 days (1.6 years).

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 14.0 years (5,103 days); Year of diagnosis: 1987; Days to last follow up: 591 days (1.6 years).

Follow-up (1 entry)
- Days to follow up: 591 days (1.6 years); Event-free: no event (relapse, second malignancy or death) recorded through day 591; Year of follow up: 1989.

Biospecimens (4 samples)
- Samples TARGET-15-SJMPAL012425-09A, TARGET-15-SJMPAL012425-09A.1, TARGET-15-SJMPAL012425-09A.2 (3 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL012425-14A.1: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 591
- Protocol: St. Jude
- Karyotype: 46,XX,inv(3)(p25q21),del(6)(q13q21),t(4;12)(q12;p13),add(7)(q36),del(10)(q24)[4]/47,idem,+15[3]/46,XX[12]
- WHO ALAL Classification: B/M
- WHO Dx: B/M
